Somatic mutation profile of tumor specimen TARGET-10-PARCLU-09A (aliquot TARGET-10-PARCLU-09A-01D) from TARGET case TARGET-10-PARCLU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.6 years (6,051 days).
Specimen TARGET-10-PARCLU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fee8d34-eacb-4628-be71-4329e8ab8664.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCLU-10A (Blood Derived Normal), aliquot TARGET-10-PARCLU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9de50fa7-0b3a-4f75-8526-4faa2f79058f

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 3, Silent 3, Splice Site 2, Intron 2, RNA 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.7903C>T p.R2635* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as rs794727549, CM114116, COSV56447739; ClinVar: pathogenic; called by muse, mutect2
- PTPN11 | c.1510A>G p.M504V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs397507547, CM013423, COSV61012722; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CAD | c.2974G>A p.D992N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867021325; called by muse, mutect2, varscan2
- CHD4 | c.2590C>T p.R864W (on ENST00000357008 / NM_001363606.2; = p.R877W on NM_001273.5) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58898273; called by muse, mutect2, varscan2
- CREBBP | c.4648G>C p.E1550Q | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52118002, COSV52134589; called by muse, mutect2, varscan2
- DLG2 | c.2149C>T p.R717* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV54658769; called by muse, mutect2, varscan2
- FOXQ1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV57258653; called by muse, mutect2, varscan2
- SNX21 | c.568A>C p.M190L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs760774166; called by muse, mutect2, varscan2
- TYK2 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs756169718, COSV53384945; called by muse, mutect2, varscan2
- WSB1 | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs777019230; called by muse, mutect2, varscan2
- CCR7 | c.209_210insGGGCCAGGCC p.F70Lfs*87 | Frame Shift Ins (INS) | VAF 23/56 reads (41%) | called by mutect2, pindel, varscan2
- HIPK3 | c.2908G>A p.V970M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PDS5B | c.705+2_705+3insGGGGGCCTT p.X235_splice | Splice Site (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel
- RIT1 | c.238-10_242delinsCCTCCCAGAC p.X80_splice | Splice Site (DEL) | VAF 7/40 reads (18%) | called by pindel, varscan2*
- TTF2 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- ABCB6 | c.2037C>T p.T679= | Silent (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- SCARA3 | c.642C>T p.Y214= | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as rs1382781531; called by muse, mutect2, varscan2
- TPP1 | c.951G>T p.L317= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- IGDCC3 | c.409+19260C>T | Intron (SNP) | VAF 4/8 reads (50%) | catalogued as rs908648190, COSV60076979; called by muse, mutect2, varscan2
- POU2F2 | c.*3G>A | 3'UTR (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
- PSORS1C2 | c.55+119T>G | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- RBM8B | n.66C>T | RNA (SNP) | VAF 13/45 reads (29%) | catalogued as rs769577713; called by muse, mutect2, varscan2
